Somatic mutation profile of tumor specimen TCGA-13-0883-01A (aliquot TCGA-13-0883-01A-02W-0420-08) from TCGA case TCGA-13-0883, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,395 days).
Specimen TCGA-13-0883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7354559-3139-44d2-aa45-2b1abffe85ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0883-10A (Blood Derived Normal), aliquot TCGA-13-0883-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0128e664-cadc-4798-8a24-9b43e18d5c2f

The open-access MAF lists 89 somatic variants for this specimen: 73 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 13, Nonsense Mutation 5, In Frame Del 3, Intron 2, Frame Shift Ins 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.714dup p.N239* | Frame Shift Ins (INS) | VAF 330/521 reads (63%) | catalogued as rs1567549651, COSV52663173, COSV52791488; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB5 | c.2654G>A p.R885H (on ENST00000404938 / NM_001163941.2; = p.R440H on NM_178559.6) | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs111647033; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2992C>A p.Q998K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV65895060; called by muse, mutect2, varscan2
- AHCYL2 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 93/514 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61489311; called by muse, mutect2, varscan2
- ANKRD35 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.298); catalogued as COSV62911002; called by muse, mutect2, varscan2
- ATXN7L2 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV63992124, COSV63992544; called by muse, mutect2, varscan2
- BIRC6 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV70202766; called by muse, mutect2, varscan2
- CABS1 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs551306523, COSV56734064; called by muse, mutect2, varscan2
- CASKIN1 | c.564C>G p.N188K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV58874606; called by muse, varscan2
- CENPF | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs1271096751, COSV65276663; called by muse, mutect2, varscan2
- CEP250 | c.3559T>C p.S1187P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.65); catalogued as COSV61171889; called by muse, mutect2
- CHAT | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100339707; called by mutect2, varscan2
- CMYA5 | c.9265G>T p.E3089* | Nonsense Mutation (SNP) | VAF 37/207 reads (18%) | catalogued as COSV71407607, COSV99069764; called by muse, mutect2, varscan2
- COL1A1 | c.1337G>C p.G446A | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56807331; called by muse, mutect2, varscan2
- CREBBP | c.3859G>C p.G1287R | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as CD1414250, COSV99268532; called by muse, mutect2, varscan2
- CUL7 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs201348693, COSV54819552; called by muse, mutect2, varscan2
- DISP1 | c.1485_1488del p.L495Ffs*6 | Frame Shift Del (DEL) | VAF 25/112 reads (22%) | catalogued as rs1462608117; called by pindel, varscan2
- ELMOD3 | c.533T>A p.I178N | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59773869; called by muse, mutect2, varscan2
- EYA1 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267601985, COSV58168060; called by muse, mutect2, varscan2
- F13A1 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 97/863 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99342160; called by mutect2, varscan2
- GRM1 | c.672G>T p.W224C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51199649; called by muse, mutect2, varscan2
- INSR | c.3140A>T p.K1047M | Missense Mutation (SNP) | VAF 154/471 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57167208; called by muse, mutect2, varscan2
- INSRR | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV63875393; called by muse, mutect2, varscan2
- KCNG1 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.92); catalogued as COSV65369763; called by muse, mutect2, varscan2
- KIAA1549 | c.5797G>A p.E1933K (on ENST00000422774 / NM_001164665.2; = p.E1917K on NM_020910.3) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1317483461, COSV99649775; called by muse, mutect2, varscan2
- LNPEP | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 30/155 reads (19%) | catalogued as COSV51479472; called by muse, mutect2, varscan2
- LTK | c.2493G>C p.W831C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1489444214, COSV53028492; called by muse, mutect2, varscan2
- MAP9 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV60905505; called by muse, mutect2, varscan2
- MBNL1 | c.1087G>A p.A363T (on ENST00000282486 / NM_207293.2; = p.A357T on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.416); catalogued as COSV56832531; called by mutect2, varscan2
- MED19 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV54708037; called by muse, mutect2, varscan2
- MIDEAS | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs773067122, COSV54096625; called by muse, mutect2, varscan2
- MST1R | c.2929G>T p.V977F | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV56571177; called by muse, mutect2, varscan2
- MYH2 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 17/454 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1198777358, COSV55435143, COSV99821044; called by muse, mutect2
- MYO10 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs376986603; called by muse, mutect2, varscan2
- NISCH | c.3694C>A p.L1232M | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58740020; called by muse, mutect2, varscan2
- NUTM1 | c.2419G>T p.G807* | Nonsense Mutation (SNP) | VAF 114/348 reads (33%) | catalogued as COSV59217832; called by muse, mutect2, varscan2
- OR10A5 | c.584T>A p.L195Q | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV55054970; called by muse, mutect2, varscan2
- PAX3 | c.1090T>G p.S364A | Missense Mutation (SNP) | VAF 152/298 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV60590218; called by muse, mutect2, varscan2
- PLCB2 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV53035649; called by muse, mutect2, varscan2
- POTEF | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV62542341; called by muse, mutect2, varscan2
- PPRC1 | c.3917dup p.M1309Dfs*47 | Frame Shift Ins (INS) | VAF 23/185 reads (12%) | catalogued as rs749215431; called by mutect2, varscan2
- RABGAP1L | c.156T>G p.D52E | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as COSV52309565; called by muse, mutect2, varscan2
- RANBP2 | c.6511G>A p.E2171K | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99311235; called by muse, mutect2
- RBM48 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV56003167; called by muse, mutect2, varscan2
- RHBG | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54807490; called by muse, mutect2, varscan2
- ROS1 | c.4483A>G p.N1495D | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs766758100, COSV63858293; called by muse, mutect2, varscan2
- SELENON | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV62525435; called by muse, mutect2, varscan2
- SLC38A1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67063648; called by muse, mutect2, varscan2
- SPRED2 | c.56T>A p.V19E | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62694309; called by muse, mutect2, varscan2
- STK26 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 252/392 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV100048667; called by muse, mutect2, varscan2
- TBX22 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64787003, COSV64787147; called by muse, mutect2, varscan2
- TG | c.7022G>T p.G2341V | Missense Mutation (SNP) | VAF 148/771 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55085334; called by muse, mutect2, varscan2
- TLL2 | c.2176A>T p.R726W | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV63573483; called by muse, mutect2
- USP2 | c.1065G>C p.Q355H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52730866; called by muse, mutect2
- USP34 | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV68403529; called by muse, mutect2, varscan2
- USP43 | c.1352A>T p.Q451L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV53300642; called by muse, varscan2
- VRK1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 200/312 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99388201; called by muse, mutect2, varscan2
- XYLT1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774302454, COSV54490381; called by muse, mutect2, varscan2
- ZFP91 | c.1497G>C p.L499F | Missense Mutation (SNP) | VAF 123/322 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100284317, COSV60160500; called by muse, mutect2, varscan2
- ZNF565 | c.973G>A p.G325S (on ENST00000355114; = p.G285S on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/596 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV58411309; called by muse, mutect2, varscan2
- ZWILCH | c.775A>G p.R259G | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV57181543; called by muse, mutect2, varscan2
- AGBL1 | c.2217_2220+12del p.X739_splice | Splice Site (DEL) | VAF 193/1187 reads (16%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.268A>T p.I90F | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2
- C1orf54 | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 316/1786 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DRD5 | c.736_747del p.T246_Y249del | In Frame Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel
- HOXA9 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.2); called by muse, mutect2
- IQGAP2 | c.1828G>C p.D610H | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- PPIG | c.1625C>A p.A542E | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.763); called by muse, mutect2
- REST | c.1721G>C p.C574S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- SAP130 | c.391_399del p.A131_P133del | In Frame Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel
- SAXO1 | c.246_257del p.P83_V86del | In Frame Del (DEL) | VAF 132/506 reads (26%) | called by mutect2, pindel, varscan2
- SIRPD | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMARCA1 | c.2813C>G p.A938G | Missense Mutation (SNP) | VAF 247/423 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ADAMTS17 | c.2838G>T p.V946= | Silent (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- ATF7IP | c.465C>A p.T155= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV53773991; called by muse, mutect2, varscan2
- COL6A6 | c.5601C>T p.A1867= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100651025, COSV62030574; called by muse, mutect2
- DLK1 | c.483C>T p.G161= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV57992582, COSV57993060; called by muse, mutect2, varscan2
- FBXW9 | c.1161G>C p.L387= (on ENST00000587955; = p.L367= on NM_032301.3) | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as COSV66710175; called by muse, mutect2, varscan2
- KHDRBS2 | c.687C>G p.T229= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV55471927; called by muse, mutect2, varscan2
- MYH4 | c.972C>A p.P324= | Silent (SNP) | VAF 11/224 reads (5%) | catalogued as rs959794627; called by muse, mutect2
- MYO1G | c.234C>G p.L78= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV51855766; called by muse, mutect2, varscan2
- NAIF1 | c.285G>T p.A95= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- NES | c.834C>A p.I278= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs754313921, COSV63961817; called by muse, mutect2, varscan2
- S100A6 | c.60C>A p.S20= | Silent (SNP) | VAF 40/203 reads (20%) | catalogued as COSV63296971; called by muse, mutect2, varscan2
- THSD7B | c.4185G>A p.E1395= (on ENST00000272643; = p.E1393= on NM_001316349.2) | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- ZEB1 | c.1497T>C p.A499= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as COSV58049427; called by muse, mutect2, varscan2
- CLCA3P | n.731T>A | RNA (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- KHDC4 | c.682-169A>C | Intron (SNP) | VAF 21/125 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.10303+1322G>T | Intron (SNP) | VAF 74/600 reads (12%) | catalogued as COSV60189074; called by muse, mutect2, varscan2
